Somatic mutation profile of tumor specimen TARGET-40-PARFTG-01A (aliquot TARGET-40-PARFTG-01A-01D) from TARGET case TARGET-40-PARFTG, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.7 years (4,987 days).
Specimen TARGET-40-PARFTG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31f4f95c-d466-44e8-859b-e005ebfff650.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PARFTG-10A (Blood Derived Normal), aliquot TARGET-40-PARFTG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6559c54-672a-4977-8edf-52c39e119659

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRYGB | c.268A>G p.R90G | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs765392296; called by muse, mutect2, varscan2
- RASEF | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 64/98 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs370094131; called by muse, mutect2, varscan2
- SLCO6A1 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs368808696; called by muse, mutect2, varscan2
- ARHGAP5 | c.3331G>T p.V1111F | Missense Mutation (SNP) | VAF 66/95 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- OR6C4 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SUPT20H | c.1179-2A>G p.X393_splice (on ENST00000350612 / NM_001014286.3; = p.X394_splice on NM_017569.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- DTNB | c.1803C>G p.S601= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as COSV56474898; called by muse, mutect2, varscan2
- GOLGA3 | c.2220C>T p.L740= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs767788001; called by muse, mutect2, varscan2
- IGSF10 | c.2820C>G p.T940= | Silent (SNP) | VAF 121/331 reads (37%) | called by muse, mutect2, varscan2
- EML5 | c.4005-112G>C | Intron (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- SEMA6A | c.343-100C>T | Intron (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- TCP10L3 | n.224A>C | RNA (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2
